Somatic mutation profile of cancer-model specimen HCM-BROD-0038-C41-85A (2D Modified Conditionally Reprogrammed Cells, passage 11; aliquot HCM-BROD-0038-C41-85A-01D-A83K-36), derived from the primary tumor of HCMI case HCM-BROD-0038-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 16.2 years (5,911 days).
Specimen HCM-BROD-0038-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99a8513f-0d25-4d2c-9f73-2ca91e82e18d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0038-C41-10A (Blood Derived Normal), aliquot HCM-BROD-0038-C41-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36741386-3524-4210-9d31-9f7311db7fa6

The open-access MAF lists 128 somatic variants for this specimen: 82 protein-altering or splice-affecting, 34 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 34, Intron 7, Nonsense Mutation 5, 5'Flank 2, 3'Flank 2, Splice Region 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 231/720 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRA2B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 290/931 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280528454, COSV101337386; called by muse, mutect2, varscan2
- CA1 | c.605C>G p.P202R | Missense Mutation (SNP) | VAF 26/778 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56279867; called by muse, mutect2
- CEP78 | c.1156G>A p.V386M (on ENST00000424347 / NM_001349840.2; = p.V387M on NM_032171.3) | Missense Mutation (SNP) | VAF 29/559 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as rs1174617592, COSV52845794; called by muse, mutect2
- DIS3 | c.1971G>A p.R657= | Splice Region (SNP) | VAF 26/250 reads (10%) | catalogued as rs1383879280; called by muse, mutect2, varscan2
- DST | c.20678A>G p.K6893R (on ENST00000361203 / NM_001374722.1; = p.K4590R on NM_015548.5) | Missense Mutation (SNP) | VAF 73/553 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1310244157; called by muse, mutect2, varscan2
- KIAA0319L | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.285); catalogued as COSV100357611, COSV57849768; called by muse, mutect2
- LRRIQ4 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 21/381 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100540286, COSV61620061; called by muse, mutect2
- PDGFRA | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 68/720 reads (9%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.956); catalogued as rs267600188, COSV57266559; called by muse, mutect2
- SHANK3 | c.4354G>A p.G1452R | Missense Mutation (SNP) | VAF 32/701 reads (5%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.993); catalogued as rs1440735830, COSV53187102; ClinVar: likely benign; called by muse, mutect2
- SLC10A2 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 22/636 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55362158; called by muse, mutect2
- THSD7A | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 94/614 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs760394880, COSV70265686; called by muse, mutect2, varscan2
- ZFPM2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 29/807 reads (4%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs1316717585, COSV65872466, COSV65873719; called by muse, mutect2
- ABCB11 | c.2116C>A p.L706M | Missense Mutation (SNP) | VAF 81/416 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ABL1 | c.2989C>G p.P997A | Missense Mutation (SNP) | VAF 93/1196 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- AC092835.1 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 28/648 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- ACSM1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 32/692 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS17 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 47/769 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL2 | c.2791G>C p.E931Q (on ENST00000370717 / NM_001366005.1; = p.E918Q on NM_012302.4) | Missense Mutation (SNP) | VAF 78/1035 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADPRS | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- AEBP1 | c.1125G>C p.E375D | Missense Mutation (SNP) | VAF 55/500 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ANO3 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 29/684 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.078); called by muse, mutect2
- ASB2 | c.197A>T p.K66M | Missense Mutation (SNP) | VAF 46/788 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); called by muse, mutect2
- ATRX | c.3313C>G p.Q1105E | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- BATF2 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 34/825 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- BATF2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 38/830 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2
- BICC1 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 84/593 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- C22orf31 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 75/643 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDCP1 | c.410T>G p.L137* | Nonsense Mutation (SNP) | VAF 35/618 reads (6%) | called by muse, mutect2
- CDON | c.3777G>T p.E1259D (on ENST00000392693 / NM_001243597.2; = p.E1236D on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/816 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CHRNA5 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 23/526 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- CPSF2 | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 28/784 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRAT | c.1383C>A p.H461Q | Missense Mutation (SNP) | VAF 30/649 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2
- DCAF1 | c.1897G>C p.V633L | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DCAF15 | c.1472A>T p.N491I | Missense Mutation (SNP) | VAF 56/688 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DENND1C | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DMXL2 | c.8890G>T p.G2964C | Missense Mutation (SNP) | VAF 12/405 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNTTIP2 | c.1484C>G p.P495R | Missense Mutation (SNP) | VAF 131/977 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAPOR2 | c.2519A>T p.N840I (on ENST00000450689 / NM_001142749.3; = p.N673I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ELAPOR2 | c.706A>T p.K236* (on ENST00000450689 / NM_001142749.3; = p.K69* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 92/410 reads (22%) | called by muse, mutect2, varscan2
- EMILIN1 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 48/864 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2
- FBH1 | c.156G>A p.R52= (on ENST00000362091 / NM_178150.3; = p.R103= on NM_032807.4) | Splice Region (SNP) | VAF 11/281 reads (4%) | called by muse, mutect2
- GABRA1 | c.289T>A p.W97R | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- GABRG3 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.309); called by muse, mutect2
- GDAP2 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 26/702 reads (4%) | called by muse, mutect2
- GDI2 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GFPT2 | c.1981C>A p.L661M | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IKZF4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 26/587 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ITPR3 | c.6371T>C p.I2124T | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- KALRN | c.6770G>T p.R2257M (on ENST00000360013 / NM_001024660.4; = p.R560M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/659 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNB2 | c.1837T>A p.F613I | Missense Mutation (SNP) | VAF 54/900 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- KCNK18 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 121/597 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK9 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 57/1023 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- KDM4C | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1522 | c.2978C>G p.T993S (on ENST00000373480 / NM_001198972.2; = p.T1052S on NM_020888.3) | Missense Mutation (SNP) | VAF 46/590 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); called by muse, mutect2
- KIF4B | c.751A>T p.K251* | Nonsense Mutation (SNP) | VAF 74/1014 reads (7%) | called by muse, mutect2
- KIF5A | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 76/856 reads (9%) | called by muse, mutect2
- KRTAP10-9 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 92/1786 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- MCCC2 | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC22 | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 141/565 reads (25%) | SIFT tolerated (0.13); called by muse, mutect2, varscan2
- MYH15 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH2 | c.5189T>C p.I1730T | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2
- NKX2-1 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 53/1200 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- NRSN1 | c.95A>C p.Q32P | Missense Mutation (SNP) | VAF 32/717 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- OR5L2 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 60/593 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- OXSM | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 29/563 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- PCDHGA1 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 50/693 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PDIA2 | c.748T>A p.F250I | Missense Mutation (SNP) | VAF 26/553 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGK2 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 53/1063 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF3 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 34/620 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- PLCH2 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 136/587 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSD4 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 28/842 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2
- RNF20 | c.2728A>G p.M910V | Missense Mutation (SNP) | VAF 13/387 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0.035); called by muse, mutect2
- SEMA3E | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEM2 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 34/870 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); called by muse, mutect2
- SSX5 | c.197C>A p.T66N (on ENST00000347757 / NM_175723.1; = p.T107N on NM_021015.4) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- STRBP | c.344_346del p.E115_T116delinsA | In Frame Del (DEL) | VAF 110/549 reads (20%) | called by mutect2, pindel, varscan2
- TBRG4 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 32/732 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- THSD7A | c.518T>A p.I173N | Missense Mutation (SNP) | VAF 98/664 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM147 | c.338T>G p.M113R | Missense Mutation (SNP) | VAF 54/533 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TXNDC11 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWCE | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 20/584 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- ALKBH4 | c.768C>T p.I256= | Silent (SNP) | VAF 86/766 reads (11%) | called by muse, mutect2, varscan2
- CAPN6 | c.714G>A p.E238= | Silent (SNP) | VAF 26/277 reads (9%) | catalogued as COSV60695805; called by muse, mutect2
- CCDC114 | c.9G>A p.G3= | Silent (SNP) | VAF 82/375 reads (22%) | catalogued as rs1441510248; called by muse, mutect2, varscan2
- CCSER2 | c.396G>A p.V132= | Silent (SNP) | VAF 77/407 reads (19%) | called by muse, mutect2, varscan2
- CHD7 | c.5454G>A p.L1818= | Silent (SNP) | VAF 88/631 reads (14%) | catalogued as rs775492728, COSV101418515; called by muse, mutect2, varscan2
- COL1A1 | c.3453C>G p.G1151= | Silent (SNP) | VAF 44/768 reads (6%) | called by muse, mutect2
- COL4A1 | c.1788T>C p.S596= | Silent (SNP) | VAF 22/565 reads (4%) | called by muse, mutect2
- CRTC3 | c.1296C>T p.S432= | Silent (SNP) | VAF 58/1036 reads (6%) | called by muse, mutect2
- CSMD1 | c.3423G>A p.K1141= (on ENST00000520002; = p.K1140= on NM_033225.6) | Silent (SNP) | VAF 29/450 reads (6%) | catalogued as rs1282549982, COSV59331484; called by muse, mutect2
- DMRTC2 | c.945C>T p.P315= | Silent (SNP) | VAF 38/796 reads (5%) | catalogued as rs1346474118; called by muse, mutect2
- DNAH9 | c.4213C>T p.L1405= | Silent (SNP) | VAF 34/779 reads (4%) | catalogued as rs1188338752; called by muse, mutect2
- ERICH5 | c.765C>T p.P255= | Silent (SNP) | VAF 31/795 reads (4%) | called by muse, mutect2
- FMN1 | c.3039G>A p.R1013= (on ENST00000616417 / NM_001277313.2; = p.R790= on NM_001103184.4) | Silent (SNP) | VAF 28/518 reads (5%) | called by muse, mutect2
- FOXL2 | c.990C>T p.A330= | Silent (SNP) | VAF 38/806 reads (5%) | called by muse, mutect2
- JHY | c.657G>A p.E219= | Silent (SNP) | VAF 28/718 reads (4%) | catalogued as rs756526451; called by muse, mutect2
- KCNQ3 | c.672C>T p.T224= | Silent (SNP) | VAF 56/980 reads (6%) | catalogued as rs768687450; called by muse, mutect2
- KLHL32 | c.6G>T p.P2= | Silent (SNP) | VAF 94/485 reads (19%) | catalogued as rs145552576; called by muse, mutect2, varscan2
- MSRA | c.423C>T p.H141= | Silent (SNP) | VAF 41/310 reads (13%) | catalogued as rs367978405; called by muse, mutect2, varscan2
- MUC12 | c.5577C>T p.S1859= (on ENST00000379442; = p.S1716= on NM_001164462.1) | Silent (SNP) | VAF 31/1558 reads (2%) | called by muse, mutect2
- OTOF | c.3795G>A p.G1265= (on ENST00000272371 / NM_194248.3; = p.G498= on NM_004802.4) | Silent (SNP) | VAF 16/636 reads (3%) | called by muse, mutect2
- PTX4 | c.633G>A p.Q211= (on ENST00000447419 / NM_001328608.2; = p.Q206= on NM_001013658.1) | Silent (SNP) | VAF 199/811 reads (25%) | catalogued as COSV53520257; called by muse, mutect2, varscan2
- QPCTL | c.687G>A p.K229= | Silent (SNP) | VAF 38/681 reads (6%) | called by muse, mutect2
- RP1 | c.51T>A p.S17= | Silent (SNP) | VAF 42/796 reads (5%) | called by muse, mutect2
- SGSM1 | c.2097G>A p.R699= | Silent (SNP) | VAF 38/512 reads (7%) | called by muse, mutect2
- SMARCAD1 | c.1872C>T p.Y624= | Silent (SNP) | VAF 28/519 reads (5%) | catalogued as rs199891976, COSV62774853; called by muse, mutect2
- SSX5 | c.198C>A p.T66= (on ENST00000347757 / NM_175723.1; = p.T107= on NM_021015.4) | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- TRPC6 | c.2158C>T p.L720= | Silent (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- TRPM4 | c.2850G>T p.G950= | Silent (SNP) | VAF 123/501 reads (25%) | catalogued as COSV53265329; called by muse, mutect2, varscan2
- UBAP2L | c.3078C>G p.A1026= | Silent (SNP) | VAF 35/989 reads (4%) | called by muse, mutect2
- UGGT2 | c.702G>A p.V234= | Silent (SNP) | VAF 41/552 reads (7%) | called by muse, mutect2
- USP6 | c.3375C>T p.P1125= | Silent (SNP) | VAF 34/962 reads (4%) | called by muse, mutect2
- ZNF334 | c.216G>A p.E72= | Silent (SNP) | VAF 22/596 reads (4%) | called by muse, mutect2
- ZNF469 | c.3292C>T p.L1098= (on ENST00000437464; = p.L1126= on NM_001367624.2) | Silent (SNP) | VAF 33/1028 reads (3%) | called by muse, mutect2
- ZSCAN2 | c.639G>A p.Q213= | Silent (SNP) | VAF 40/1166 reads (3%) | called by muse, mutect2
- AL132655.6 | chr20:58839861 C>T | 5'Flank (SNP) | VAF 111/540 reads (21%) | called by muse, mutect2, varscan2
- CAMKK1 | c.685+168C>A | Intron (SNP) | VAF 20/543 reads (4%) | called by muse, mutect2
- CRMP1 | chr4:5889655 C>T | 5'Flank (SNP) | VAF 55/464 reads (12%) | called by muse, mutect2, varscan2
- FAM184A | c.1815+340A>G | Intron (SNP) | VAF 62/493 reads (13%) | called by muse, mutect2, varscan2
- FOXP1 | c.1652+476C>T | Intron (SNP) | VAF 25/811 reads (3%) | called by muse, mutect2
- KIR3DX1 | n.242A>G | RNA (SNP) | VAF 54/620 reads (9%) | catalogued as rs768263281; called by muse, mutect2
- LCORL | chr4:17876543 A>T | 3'Flank (SNP) | VAF 20/475 reads (4%) | called by muse, mutect2
- LCORL | chr4:17876750 T>G | 3'Flank (SNP) | VAF 18/458 reads (4%) | catalogued as rs1256009706; called by muse, mutect2
- LDAH | c.298+1011A>G | Intron (SNP) | VAF 133/628 reads (21%) | called by muse, mutect2, varscan2
- NPC2 | c.441+33G>T | Intron (SNP) | VAF 31/877 reads (4%) | called by muse, mutect2
- NPC2 | c.441+32T>A | Intron (SNP) | VAF 31/882 reads (4%) | called by muse, mutect2
- TANGO2 | c.56+214A>T | Intron (SNP) | VAF 27/590 reads (5%) | called by muse, mutect2
